Somatic mutation profile of tumor specimen TCGA-VS-A958-01A (aliquot TCGA-VS-A958-01A-11D-A42O-09) from TCGA case TCGA-VS-A958, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 46.3 years (16,905 days).
Specimen TCGA-VS-A958-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa9a0b1d-915f-4a6e-8f4f-ee464a3f5465.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A958-10A (Blood Derived Normal), aliquot TCGA-VS-A958-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b196026-e571-4e6d-9d1c-31b1d4472d4d

The open-access MAF lists 888 somatic variants for this specimen: 652 protein-altering or splice-affecting, 215 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 579, Silent 215, Nonsense Mutation 50, Splice Site 12, Intron 9, Splice Region 6, RNA 4, 5'UTR 3, Frame Shift Del 2, 3'Flank 2, Nonstop Mutation 2, 3'UTR 2.

Variants (750 of 888; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2
- KMT2D | c.4204C>T p.Q1402* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs1555195442, COSV56443229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 32/138 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2107-1G>C p.X703_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as rs587778860, CS125752, COSV57297199, COSV57304025; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99771145, COSV99771733; called by muse, mutect2, varscan2
- ABAT | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as rs752701740, COSV51628875, COSV99191044; called by muse, mutect2, varscan2
- ABCA2 | c.6963G>C p.Q2321H (on ENST00000614293; = p.Q2291H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs763393431, COSV99688553; called by muse, mutect2
- ABCA9 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV100383576, COSV100383712; called by muse, mutect2, varscan2
- ABCC5 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99657716; called by muse, mutect2, varscan2
- ABHD11 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99766964; called by muse, mutect2, varscan2
- ABHD8 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV99917392; called by muse, mutect2, varscan2
- ABI1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV100698064; called by muse, mutect2, varscan2
- ABR | c.1352G>A p.R451K (on ENST00000302538 / NM_021962.5; = p.R414K on NM_001092.5) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV99348729; called by muse, mutect2, varscan2
- ACAN | c.2936G>C p.G979A | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100719399; called by muse, mutect2, varscan2
- ACE2 | c.2408C>T p.T803I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); catalogued as COSV99383158; called by muse, mutect2, varscan2
- ACKR3 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV99799873; called by muse, mutect2, varscan2
- ACSF3 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs1337470176, COSV100441634; called by muse, mutect2, varscan2
- ADAM2 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as COSV99697987; called by muse, mutect2, varscan2
- ADAMTS16 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.198); catalogued as rs766063759, COSV99943307; called by mutect2, varscan2
- ADAMTSL4 | c.2727G>C p.E909D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.788); catalogued as COSV99648127; called by muse, mutect2, varscan2
- ADGRG1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV101113586; called by muse, mutect2, varscan2
- AGBL2 | c.2116A>G p.S706G | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV100102200; called by muse, varscan2
- AGT | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100794495; called by muse, mutect2, varscan2
- AHNAK | c.4716G>C p.M1572I | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV99949899; called by muse, mutect2
- AIM2 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as COSV100931161, COSV63699155; called by muse, mutect2, varscan2
- AKAP11 | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as COSV99214420; called by muse, mutect2, varscan2
- AKAP9 | c.11545G>A p.E3849K (on ENST00000359028; = p.E3825K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs753830750, COSV99134187; called by muse, mutect2, varscan2
- AKR1B10 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as rs1211443532, COSV100610265, COSV62056569; called by muse, mutect2, varscan2
- ALDH1A1 | c.1497G>C p.K499N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99921707; called by muse, mutect2, varscan2
- ALG13 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV99323169; called by muse, mutect2, varscan2
- ALG13 | c.2993G>C p.W998S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52638763, COSV99323173; called by muse, mutect2, varscan2
- AMOTL2 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777567348, COSV99998350; called by muse, mutect2, varscan2
- ANAPC5 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV99946540, COSV99946571; called by muse, mutect2, varscan2
- ANKRD26 | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV101063461; called by muse, mutect2, varscan2
- ANXA2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100222168; called by muse, mutect2, varscan2
- AOX1 | c.2360C>T p.S787L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV101022257; called by muse, mutect2, varscan2
- AP4B1 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56726703, COSV99871191; called by muse, mutect2, varscan2
- AP4E1 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99957273; called by muse, mutect2, varscan2
- APAF1 | c.815C>T p.S272L (on ENST00000551964 / NM_181861.2; = p.S261L on NM_001160.3) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV100244472; called by muse, mutect2, varscan2
- APBA2 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV101258221; called by muse, mutect2, varscan2
- APOBR | c.2701G>A p.E901K (on ENST00000431282; = p.E910K on NM_018690.4) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100112981; called by muse, mutect2, varscan2
- AQR | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as COSV99334828; called by muse, mutect2, varscan2
- ARG1 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV51580808, COSV99256308; called by muse, mutect2, varscan2
- ARGLU1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100639793; called by muse, mutect2, varscan2
- ARHGAP29 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV99559165; called by muse, mutect2, varscan2
- ARHGEF4 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100388805; called by muse, mutect2, varscan2
- ARMC2 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100933684; called by muse, mutect2, varscan2
- ASAP3 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100369756; called by muse, mutect2, varscan2
- ASB5 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533097681, COSV56672675, COSV56675068; called by muse, mutect2, varscan2
- ASCC1 | c.652G>A p.E218K (on ENST00000342444 / NM_001369085.1; = p.E190K on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV100403848; called by muse, mutect2, varscan2
- ATAD2B | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.042); catalogued as COSV99478576; called by muse, mutect2, varscan2
- ATRAID | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV100143637; called by muse, mutect2, varscan2
- ATRX | c.6666G>C p.K2222N | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV100971550, COSV100971557; called by muse, mutect2, varscan2
- ATXN1 | c.1442A>T p.H481L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99788083; called by muse, mutect2, varscan2
- AVIL | c.2375C>G p.S792C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV99142700; called by muse, mutect2, varscan2
- BAG6 | c.1069C>G p.H357D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99277721; called by mutect2, varscan2
- BANK1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1428281031, COSV59850255; called by muse, mutect2
- BEX5 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV100375093; called by muse, mutect2, varscan2
- BHLHE40 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99848323; called by muse, mutect2, varscan2
- BIRC6 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV101429067; called by muse, mutect2, varscan2
- BIRC6 | c.12314C>T p.S4105F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV101429068; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4892G>A p.R1631K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.32); catalogued as COSV100863979; called by muse, mutect2, varscan2
- BLM | c.1297G>C p.D433H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV100757351; called by muse, mutect2, varscan2
- BLM | c.2704G>C p.D902H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100757352; called by muse, mutect2, varscan2
- BLM | c.4159C>G p.Q1387E | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0.104); catalogued as COSV100757353; called by muse, mutect2, varscan2
- BOD1L1 | c.5482A>T p.S1828C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV99240534; called by muse, mutect2, varscan2
- BPNT2 | c.388-1G>A p.X130_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99388880, COSV99389301; called by muse, mutect2, varscan2
- BRCA1 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100525213; called by muse, mutect2, varscan2
- BRWD1 | c.3727G>C p.E1243Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.322); catalogued as COSV100314278, COSV60904026; called by muse, mutect2, varscan2
- BRWD3 | c.4388G>A p.G1463E | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100955860; called by muse, mutect2, varscan2
- BYSL | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539386229, COSV100026978; called by muse, mutect2, varscan2
- C12orf65 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.663); catalogued as rs768652922, COSV99474069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C15orf39 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs201945099, COSV100641503; called by muse, mutect2, varscan2
- C16orf46 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100215483; called by muse, mutect2, varscan2
- CABP4 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs966008036, COSV56885213; called by muse, mutect2, varscan2
- CABP5 | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV99506749; called by muse, mutect2, varscan2
- CACNA1A | c.2887C>T p.R963C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100803338; called by muse, mutect2, varscan2
- CACNA1A | c.1364G>C p.R455P | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803340, COSV64204135; called by muse, mutect2, varscan2
- CACNA1H | c.7061A>T p.*2354Lext*36 | Nonstop Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99327143; called by muse, mutect2, varscan2
- CACNA2D4 | c.2623G>A p.V875M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.208); catalogued as rs199781150; called by muse, mutect2, varscan2
- CACNB4 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs751883436, COSV52394340; called by muse, mutect2, varscan2
- CAD | c.1562G>C p.R521T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99255608, COSV99255913; called by muse, mutect2, varscan2
- CARS2 | c.599G>C p.R200T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.348); catalogued as COSV99960068; called by muse, varscan2
- CASP8 | c.1165C>T p.Q389* (on ENST00000432109 / NM_033355.3; = p.Q406* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs747862347, COSV51851572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERE | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV63678022; called by muse, mutect2, varscan2
- CC2D1A | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.922); catalogued as rs946573166, COSV100528744, COSV58781155; called by muse, mutect2, varscan2
- CC2D1A | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as COSV100528745; called by muse, mutect2, varscan2
- CCDC186 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.866); catalogued as COSV100991144; called by muse, mutect2, varscan2
- CCNB2 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99879202; called by muse, mutect2, varscan2
- CCNJL | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99979874; called by muse, mutect2, varscan2
- CD101 | c.2666C>G p.S889C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV99870226; called by muse, mutect2, varscan2
- CD200 | c.309C>G p.F103L (on ENST00000473539 / NM_001004196.3; = p.F78L on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100238509; called by muse, mutect2, varscan2
- CD69 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV57302319; called by muse, mutect2, varscan2
- CD84 | c.1024G>A p.E342K (on ENST00000311224 / NM_001184879.2; = p.E325K on NM_003874.4) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV60870761; called by muse, mutect2, varscan2
- CDH11 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs760470953, COSV51774311; called by muse, mutect2, varscan2
- CDK12 | c.2268G>C p.K756N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101420557; called by muse, mutect2, varscan2
- CEACAM3 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55760630, COSV99705140; called by muse, mutect2
- CFAP54 | c.6079C>T p.Q2027* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV61571591; called by muse, mutect2, varscan2
- CHD7 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV101418503; called by muse, mutect2, varscan2
- CHD7 | c.5629G>C p.E1877Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV101418505; called by muse, mutect2, varscan2
- CHL1 | c.1948G>A p.E650K (on ENST00000397491 / NM_001253387.1; = p.E666K on NM_006614.4) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99852548; called by muse, mutect2, varscan2
- CHRNB2 | c.1490C>G p.S497* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as COSV100872516; called by muse, mutect2, varscan2
- CHUK | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100957290; called by muse, mutect2, varscan2
- CLDN10 | c.21G>C p.E7D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100176296; called by muse, mutect2, varscan2
- CLEC16A | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.152); catalogued as COSV101278564; called by muse, mutect2, varscan2
- CLSPN | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99231623; called by muse, mutect2, varscan2
- CMBL | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99687274; called by muse, mutect2, varscan2
- CNBD2 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100839184; called by muse, mutect2, varscan2
- COL4A2 | c.2909G>A p.R970Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1229599196, COSV100847510; called by muse, mutect2
- COL5A3 | c.4078C>T p.R1360* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99318423; called by muse, mutect2, varscan2
- COL6A3 | c.6605G>A p.R2202Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs768050320, COSV55091677; called by muse, mutect2, varscan2
- COLEC10 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs866748212, COSV100250946; called by muse, mutect2, varscan2
- CPEB3 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.276); catalogued as rs1436741306; called by muse, mutect2
- CPT1B | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV100376876; called by muse, mutect2, varscan2
- CRISPLD2 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV99296093; called by muse, mutect2, varscan2
- CSF2RB | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs570881311, COSV99454546; called by muse, mutect2, varscan2
- CSF2RB | c.1465-1G>C p.X489_splice | Splice Site (SNP) | VAF 26/103 reads (25%) | catalogued as COSV99454547; called by muse, mutect2, varscan2
- CSNK1D | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1474323699, COSV53927526; called by muse, mutect2, varscan2
- CSNK1G1 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100274540; called by muse, mutect2, varscan2
- CSRNP2 | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99950539; called by muse, mutect2, varscan2
- CYP3A5 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99770157; called by muse, mutect2, varscan2
- DAGLA | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs771001941, COSV57197210; called by muse, mutect2, varscan2
- DBI | c.19G>C p.E7Q (on ENST00000355857 / NM_001079862.3; = p.E24Q on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100276070; called by muse, mutect2, varscan2
- DCAF17 | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as COSV100266408; called by muse, mutect2, varscan2
- DCAF8 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV100470931, COSV58785617; called by muse, mutect2, varscan2
- DCDC1 | c.1911C>G p.F637L | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100664280; called by muse, mutect2
- DDIT3 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100007736; called by muse, mutect2, varscan2
- DDX3X | c.389C>G p.S130* (on ENST00000399959; = p.S131* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 42/125 reads (34%) | catalogued as COSV101302530, COSV67864007; called by muse, mutect2, varscan2
- DEF6 | c.1720C>G p.L574V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100359568; called by muse, mutect2, varscan2
- DGKH | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV99819688; called by muse, mutect2, varscan2
- DHX30 | c.2784G>C p.L928F (on ENST00000445061 / NM_138615.3; = p.L889F on NM_014966.3) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.219); catalogued as COSV99276449; called by muse, mutect2, varscan2
- DHX40 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.099); catalogued as COSV99233301; called by muse, mutect2
- DICER1 | c.4981C>T p.H1661Y | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.95); catalogued as COSV100602109; called by muse, mutect2, varscan2
- DISP3 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV53825748; called by muse, mutect2, varscan2
- DLC1 | c.3724G>A p.E1242K (on ENST00000276297 / NM_001348081.2; = p.E805K on NM_006094.5) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV52325559; called by muse, mutect2, varscan2
- DLGAP1 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234257; called by muse, mutect2, varscan2
- DNAH10 | c.3830G>C p.G1277A (on ENST00000409039; = p.G1216A on NM_207437.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV101292885, COSV68993522; called by muse, mutect2, varscan2
- DNAH5 | c.11432C>T p.S3811L | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99454940; called by muse, mutect2, varscan2
- DNAI2 | c.1407C>G p.C469W | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100210152; called by muse, mutect2, varscan2
- DNAJC10 | c.2266-1G>C p.X756_splice | Splice Site (SNP) | VAF 53/206 reads (26%) | catalogued as COSV99899654; called by muse, mutect2, varscan2
- DNPEP | c.804C>G p.I268M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99815437; called by muse, mutect2, varscan2
- DOCK8 | c.2448C>G p.F816L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101210101; called by muse, mutect2, varscan2
- DOLPP1 | c.363-1G>A p.X121_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100588479; called by muse, mutect2, varscan2
- DPP8 | c.2591G>C p.R864T (on ENST00000341861 / NM_001320875.2; = p.R748T on NM_017743.6) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202655; called by muse, mutect2, varscan2
- DSCAM | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs752824503, COSV68033230, COSV68034775; called by muse, mutect2, varscan2
- DSG2 | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV55196413, COSV99853600; called by muse, mutect2, varscan2
- DSG2 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as COSV99853604; called by muse, mutect2, varscan2
- DSP | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs1164941405, COSV101131832; called by muse, mutect2, varscan2
- DSP | c.2484G>T p.M828I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV101131834; called by muse, mutect2, varscan2
- DUSP1 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV99496078; called by muse, mutect2, varscan2
- DUSP15 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99640307; called by muse, mutect2, varscan2
- DYSF | c.3220C>G p.L1074V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as CD1414197, COSV99244779; called by muse, mutect2, varscan2
- DYSF | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50323682, COSV99244041; called by muse, mutect2, varscan2
- EDDM3A | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100473461; called by muse, mutect2, varscan2
- EDDM3B | c.408A>G p.I136M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs560839911, COSV100460920; called by muse, varscan2
- EFCAB1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100031020; called by muse, mutect2, varscan2
- EHD2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99622281; called by muse, mutect2, varscan2
- EIF2AK4 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.652); catalogued as COSV99775460; called by muse, mutect2, varscan2
- ELK1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV99902385; called by muse, mutect2, varscan2
- ENKUR | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482289; called by muse, mutect2, varscan2
- ENO1 | c.1236-1G>A p.X412_splice | Splice Site (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99319023; called by muse, mutect2, varscan2
- ENTPD7 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV100978505; called by muse, mutect2, varscan2
- EP300 | c.1209G>A p.W403* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV54335581; called by muse, mutect2, varscan2
- EPG5 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99958224; called by muse, mutect2, varscan2
- EPHA10 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100140194; called by muse, mutect2
- EPM2AIP1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.107); catalogued as COSV99212826; called by muse, mutect2, varscan2
- ERBIN | c.2167C>T p.H723Y | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); catalogued as rs1343781763, COSV99397945; called by muse, mutect2, varscan2
- ERC1 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as COSV100706844, COSV61691525; called by muse, mutect2, varscan2
- ERCC3 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.139); catalogued as COSV99573725; called by muse, mutect2, varscan2
- ERF | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99724868; called by muse, mutect2, varscan2
- ERMN | c.242-1G>A p.X81_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV101263074, COSV68075734; called by muse, mutect2, varscan2
- ESCO1 | c.2128C>G p.L710V | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99332656; called by muse, mutect2, varscan2
- ETV2 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV99877014; called by muse, varscan2
- EVI2A | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV99907735; called by muse, mutect2
- EVI5L | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs1337450855, COSV99563621; called by muse, mutect2, varscan2
- EVL | c.403G>C p.D135H (on ENST00000402714 / NM_001330221.2; = p.D137H on NM_016337.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV101233140; called by muse, mutect2, varscan2
- FAM120A | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV52905021; called by muse, mutect2, varscan2
- FAM122A | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99599927; called by muse, mutect2
- FAM167B | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as rs368102614; called by muse, mutect2, varscan2
- FAM217A | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51162111; called by muse, mutect2, varscan2
- FAT2 | c.2746G>C p.E916Q | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV99944285; called by muse, mutect2, varscan2
- FBXO4 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99715329; called by muse, mutect2
- FCGR3B | c.54G>T p.M18I | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99670800; called by muse, mutect2, varscan2
- FERMT3 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99656885; called by muse, mutect2, varscan2
- FGF13 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV101003635; called by muse, mutect2, varscan2
- FILIP1 | c.2356C>T p.L786F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV99386275; called by muse, mutect2, varscan2
- FKBP15 | c.3043G>T p.E1015* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV53034811, COSV99440070; called by muse, mutect2, varscan2
- FKBP15 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99440074; called by muse, mutect2, varscan2
- FLG | c.10189G>A p.E3397K | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100912338; called by muse, mutect2, varscan2
- FLNB | c.6691G>A p.E2231K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV99915219; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99880642; called by muse, mutect2, varscan2
- FMNL3 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV99527102; called by muse, mutect2, varscan2
- FMO5 | c.126G>C p.W42C | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567560; called by muse, mutect2, varscan2
- FN3K | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as rs763485150, COSV100333403, COSV56183283; called by muse, varscan2
- FNBP1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs764532868, COSV100852826; called by muse, mutect2, varscan2
- FOXD2 | c.658C>G p.R220G | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100599331; called by muse, mutect2, varscan2
- FOXS1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV99640305; called by muse, mutect2, varscan2
- FRAS1 | c.8905G>C p.E2969Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as COSV99356201; called by muse, mutect2, varscan2
- FREM1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100772228; called by muse, mutect2, varscan2
- FRMPD1 | c.4597C>T p.Q1533* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV100899660, COSV66702201; called by muse, mutect2, varscan2
- FSCN1 | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs1416207693, COSV100435315; called by muse, mutect2, varscan2
- FUCA2 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.07); catalogued as COSV99136267; called by muse, mutect2, varscan2
- FUCA2 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as COSV50020031, COSV99136271; called by muse, mutect2, varscan2
- FUT2 | c.149C>G p.S50* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as COSV101218164; called by muse, mutect2, varscan2
- FUT8 | c.1720G>A p.E574K (on ENST00000360689 / NM_001371534.1; = p.E411K on NM_004480.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs765246656, COSV100651810; called by muse, mutect2, varscan2
- GABRD | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101059587, COSV66080461; called by muse, mutect2, varscan2
- GALNT14 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100205712; called by muse, mutect2, varscan2
- GAPVD1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as rs374437143; called by muse, mutect2, varscan2
- GAS6 | c.320C>G p.S107* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100582325; called by muse, mutect2, varscan2
- GBA | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs1557902631, CM057094, CM077547, COSV100516509, COSV59171182; called by muse, mutect2, varscan2
- GBP5 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1223761206, COSV100600142, COSV58592434; called by muse, mutect2, varscan2
- GCAT | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99959966; called by muse, mutect2, varscan2
- GCFC2 | c.266-1G>A p.X89_splice | Splice Site (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100319457; called by muse, mutect2, varscan2
- GDAP2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1358657059, COSV101032201; called by muse, mutect2, varscan2
- GIMAP4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as rs753376384, COSV55431855; called by muse, mutect2, varscan2
- GLI3 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757597719, COSV67887123, COSV67890608; called by muse, mutect2, varscan2
- GLT1D1 | c.275A>T p.N92I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV99897781; called by muse, mutect2, varscan2
- GMEB1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs867578898, COSV53793923; called by muse, mutect2, varscan2
- GMPS | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99903466; called by muse, mutect2, varscan2
- GMPS | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as COSV55809862, COSV99903467; called by muse, mutect2, varscan2
- GNPDA1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100257710; called by muse, mutect2, varscan2
- GON4L | c.4507G>A p.E1503K | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs924285069, COSV55194720; called by muse, varscan2
- GON4L | c.4122G>C p.Q1374H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99675948; called by muse, mutect2, varscan2
- GON4L | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55190090; called by muse, mutect2, varscan2
- GPAM | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100788455; called by muse, mutect2, varscan2
- GPATCH4 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577008; called by muse, mutect2, varscan2
- GPR1 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as COSV101329874; called by muse, mutect2, varscan2
- GPR149 | c.1852C>G p.H618D | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101078794; called by muse, mutect2, varscan2
- GPR149 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101078796; called by muse, mutect2, varscan2
- GRAMD2B | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV53506678, COSV53507260; called by muse, mutect2, varscan2
- GSS | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs531425565, COSV99404639; called by muse, mutect2
- GTF2I | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100260053; called by muse, mutect2, varscan2
- H2AC14 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | catalogued as COSV100297692; called by muse, mutect2
- H2AC15 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57585632, COSV57586672; called by muse, mutect2, varscan2
- HCK | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99394684; called by muse, mutect2, varscan2
- HCN3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100751947; called by muse, mutect2, varscan2
- HECTD1 | c.3036G>C p.L1012F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101237549; called by muse, mutect2, varscan2
- HECTD2 | c.527C>G p.S176* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as COSV99979041; called by muse, mutect2, varscan2
- HEG1 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV60760773; called by muse, varscan2
- HHIP | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV56842435, COSV99666400; called by muse, mutect2, varscan2
- HHIPL1 | c.677C>G p.S226W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759273355, COSV100415038, COSV58091614; called by muse, mutect2, varscan2
- HJURP | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100982649; called by muse, mutect2
- HKDC1 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100664809; called by muse, mutect2, varscan2
- HMCN1 | c.4257C>G p.F1419L | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.428); catalogued as COSV99636800; called by muse, mutect2
- HMMR | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 111/172 reads (65%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as rs1459206064, COSV100701064; called by muse, mutect2, varscan2
- HOXA3 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV57828926; called by muse, mutect2, varscan2
- HPD | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV100000249; called by muse, mutect2, varscan2
- HPDL | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV100588217; called by muse, mutect2, varscan2
- HS2ST1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV100777871; called by muse, mutect2, varscan2
- HS3ST4 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV100501730; called by muse, mutect2, varscan2
- HSH2D | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV99507512; called by muse, mutect2, varscan2
- HSP90AB1 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV62334504, COSV62336891; called by muse, mutect2, varscan2
- HTRA1 | c.1179-2A>T p.X393_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100934806; called by muse, varscan2
- IDH3G | c.1017C>G p.L339= | Splice Region (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99473467; called by muse, mutect2, varscan2
- IFT122 | c.3260C>G p.S1087C (on ENST00000348417 / NM_052989.3; = p.S1028C on NM_018262.4) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99959942; called by muse, mutect2, varscan2
- IFT122 | c.3313G>A p.E1105K (on ENST00000348417 / NM_052989.3; = p.E1046K on NM_018262.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV99959945; called by muse, mutect2, varscan2
- IGF2BP2 | c.1695C>G p.F565L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100649564; called by muse, mutect2, varscan2
- IGF2R | c.5029G>A p.D1677N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100808296; called by muse, varscan2
- IGSF9 | c.2498C>G p.P833R (on ENST00000368094 / NM_001135050.2; = p.P817R on NM_020789.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100231390; called by mutect2, varscan2
- IL17RE | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99925332; called by muse, mutect2, varscan2
- IL36G | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs143518613; called by muse, mutect2, varscan2
- IMPG2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV51975926; called by muse, mutect2, varscan2
- IQCG | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV54562810; called by muse, mutect2, varscan2
- IRF4 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66704532, COSV66705920; called by muse, mutect2, varscan2
- IRS4 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100929784; called by muse, mutect2
- ISL2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99320906; called by muse, mutect2, varscan2
- ITGAX | c.2926G>C p.E976Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.048); catalogued as COSV99192065; called by muse, mutect2, varscan2
- ITGB6 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs776446082, COSV99325063; called by muse, mutect2, varscan2
- ITLN2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV100600765; called by muse, mutect2, varscan2
- ITPR1 | c.8017G>C p.D2673H (on ENST00000354582; = p.D2618H on NM_002222.7) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100233444; called by muse, mutect2, varscan2
- IVNS1ABP | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV100832880; called by muse, mutect2, varscan2
- JPH3 | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99414128; called by muse, mutect2, varscan2
- KALRN | c.2944G>T p.E982* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99567633; called by muse, mutect2, varscan2
- KAT6A | c.5597C>G p.S1866C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs181712540; called by muse, mutect2, varscan2
- KCNIP1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 104/178 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100200216; called by muse, mutect2, varscan2
- KCNRG | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100466597; called by muse, mutect2, varscan2
- KDM7A | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV50093143; called by muse, mutect2, varscan2
- KIAA1210 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV101274217, COSV101274433; called by muse, mutect2, varscan2
- KIAA1549L | c.5038G>A p.D1680N (on ENST00000321505; = p.D1977N on NM_012194.3) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as rs781626689, COSV58592324; called by muse, mutect2, varscan2
- KIF5B | c.2137C>G p.Q713E | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV100192472; called by muse, mutect2
- KIRREL1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); catalogued as rs778087275, COSV63288541; called by muse, mutect2, varscan2
- KIT | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1060502569, COSV55407295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KL | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV66308031; called by muse, mutect2, varscan2
- KL | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101199232, COSV66308147; called by muse, mutect2, varscan2
- KLC4 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99432674; called by muse, mutect2, varscan2
- KLF7 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100519433; called by muse, mutect2, varscan2
- KMT2C | c.7261C>G p.Q2421E | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV100077379, COSV51442535; called by muse, mutect2, varscan2
- KMT2C | c.6481C>T p.Q2161* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV51427691; called by muse, mutect2, varscan2
- KMT2C | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV51449755; called by muse, mutect2, varscan2
- KNTC1 | c.2549G>C p.G850A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100338877; called by muse, mutect2, varscan2
- KRT72 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV99537520; called by muse, mutect2, varscan2
- KSR1 | c.1648G>C p.E550Q (on ENST00000644974 / NM_001367810.1; = p.E435Q on NM_014238.2) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as COSV99260991; called by muse, mutect2, varscan2
- LCAT | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99863347; called by muse, mutect2, varscan2
- LCK | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100288214; called by muse, mutect2, varscan2
- LCOR | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV53717853, COSV99617239; called by muse, mutect2, varscan2
- LGMN | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100606031; called by muse, mutect2, varscan2
- LIG1 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173320241, COSV99619398; called by muse, mutect2, varscan2
- LILRA1 | c.1020G>C p.E340D | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as COSV99252263; called by muse, mutect2, varscan2
- LILRB2 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as rs3900844, COSV100079715; called by muse, mutect2, varscan2
- LILRB5 | c.960C>G p.I320M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV60260147; called by muse, mutect2, varscan2
- LMX1B | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV100827311; called by muse, mutect2, varscan2
- LRP4 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.171); catalogued as COSV101066912; called by muse, mutect2, varscan2
- LRP5 | c.3681C>G p.I1227M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99592720; called by muse, mutect2, varscan2
- LRP8 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV100037005; called by muse, varscan2
- LRRC17 | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV99978717; called by muse, mutect2, varscan2
- LRRC23 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV99145370; called by muse, mutect2, varscan2
- LRRC27 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100689999; called by muse, mutect2, varscan2
- LRRC37B | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV58953237; called by muse, mutect2, varscan2
- LRRC37B | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as COSV100496563; called by muse, mutect2, varscan2
- LRRC43 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100337011; called by muse, mutect2, varscan2
- LRRC43 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100337012; called by muse, mutect2, varscan2
- LRRC8C | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968484; called by muse, mutect2, varscan2
- LRRN4CL | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99628568; called by muse, mutect2
- LTN1 | c.5003G>A p.R1668K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.622); catalogued as COSV100798267; called by muse, mutect2, varscan2
- LTN1 | c.4336G>C p.E1446Q | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as COSV100798269; called by muse, mutect2, varscan2
- LVRN | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs762129111, COSV100773704; called by muse, mutect2, varscan2
- LYRM1 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99534035; called by muse, mutect2, varscan2
- MACROD2 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV99444836; called by muse, mutect2, varscan2
- MAFB | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs1268494486, COSV64826376; called by muse, mutect2, varscan2
- MAMDC4 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1383747941, COSV56031702; called by muse, mutect2, varscan2
- MAP3K20 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100919650, COSV64377576; called by muse, mutect2, varscan2
- MAP4K1 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101204438; called by muse, mutect2, varscan2
- MAPK4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs186595195, COSV68541012; called by muse, mutect2, varscan2
- MAPK8IP1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53797785; called by muse, mutect2, varscan2
- MARCHF10 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); catalogued as rs774433495, COSV100248688; called by muse, mutect2, varscan2
- MBD6 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as rs148047385; called by muse, mutect2, varscan2
- MBD6 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV63073994, COSV63076534; called by muse, mutect2, varscan2
- MC3R | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.691); catalogued as rs1568966728, COSV99710894; called by muse, mutect2, varscan2
- MCAM | c.224G>C p.R75P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.746); catalogued as COSV50680965, COSV99877997; called by muse, mutect2
- MCF2L | c.1030C>G p.Q344E (on ENST00000375608; = p.Q312E on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100982573, COSV100983098; called by muse, mutect2, varscan2
- MDH1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99251348; called by muse, mutect2, varscan2
- MEF2D | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV100560437; called by muse, mutect2
- MEGF8 | c.7578C>G p.I2526M (on ENST00000251268 / NM_001271938.2; = p.I2459M on NM_001410.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99239433; called by muse, mutect2, varscan2
- MET | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100577451; called by muse, mutect2
- MGA | c.8017C>T p.H2673Y (on ENST00000219905 / NM_001164273.1; = p.H2464Y on NM_001080541.2) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as COSV99581857; called by muse, mutect2, varscan2
- MLPH | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV99222778; called by muse, mutect2, varscan2
- MMP27 | c.342-1G>A p.X114_splice | Splice Site (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99498740; called by muse, mutect2, varscan2
- MOB3C | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.344); catalogued as COSV99596515; called by muse, mutect2
- MOGS | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV52028925, COSV99281164; called by muse, mutect2, varscan2
- MORC1 | c.2386G>C p.V796L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99227985; called by muse, mutect2, varscan2
- MPST | c.856G>A p.E286K (on ENST00000341116 / NM_001369904.2; = p.E306K on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs377346580; called by muse, mutect2, varscan2
- MRE11 | c.952C>G p.P318A | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV100120129, COSV60580382; called by muse, mutect2, varscan2
- MRPS7 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV99821750; called by muse, mutect2
- MSRB1 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99238522; called by muse, varscan2
- MSX2 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV53327576; called by muse, mutect2, varscan2
- MT1H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV60090520; called by muse, mutect2
- MTCH1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.025); catalogued as COSV101010228, COSV65321110; called by muse, mutect2
- MTCL1 | c.1264G>C p.E422Q (on ENST00000306329 / NM_001378206.1; = p.E62Q on NM_015210.4) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100095736; called by muse, mutect2, varscan2
- MTSS2 | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100116741; called by muse, mutect2, varscan2
- MUC1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.336); catalogued as COSV100104914; called by muse, mutect2, varscan2
- MUC16 | c.29828C>G p.S9943C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.923); catalogued as COSV101201945, COSV104432148; called by muse, mutect2, varscan2
- MUC16 | c.20830G>A p.E6944K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); catalogued as COSV101201946; called by muse, mutect2
- MUC5B | c.15176C>T p.S5059L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs199819779, COSV71595598; called by muse, mutect2, varscan2
- MUC6 | c.6234C>G p.F2078L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs543051922, COSV70142543; called by muse, varscan2
- MVB12A | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100396638; called by muse, mutect2, varscan2
- MYBL1 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101576617; called by muse, mutect2
- MYH15 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1331326244, COSV99844439; called by muse, mutect2, varscan2
- MYL9 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1353444100, COSV99641200; called by muse, mutect2, varscan2
- MYO1D | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100553386; called by muse, mutect2, varscan2
- MYO1E | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV99896782; called by muse, mutect2, varscan2
- MZF1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs369603668; called by muse, mutect2, varscan2
- NBR1 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100358022; called by muse, mutect2, varscan2
- NCBP3 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99339738; called by muse, mutect2, varscan2
- NCF1 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV99194332; called by muse, mutect2, varscan2
- NCKAP5 | c.5594G>A p.R1865K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV100494625; called by muse, mutect2, varscan2
- NDUFB6 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100598365; called by muse, mutect2, varscan2
- NEB | c.12349G>A p.E4117K | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51460662; called by muse, mutect2, varscan2
- NEURL4 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV100224817; called by muse, mutect2, varscan2
- NEUROG3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV54343160; called by muse, mutect2, varscan2
- NFKBIA | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV53751744, COSV53752537, COSV53753434; called by muse, mutect2, varscan2
- NFKBIB | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100548548; called by muse, mutect2, varscan2
- NFU1 | c.748G>C p.E250Q (on ENST00000410022 / NM_001002755.4; = p.E226Q on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100361375; called by muse, mutect2, varscan2
- NGEF | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV50945451, COSV99891164; called by muse, varscan2
- NIPAL3 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.971); catalogued as COSV99135611; called by muse, mutect2, varscan2
- NIPBL | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as COSV99242951; called by muse, mutect2, varscan2
- NIPBL | c.3945C>G p.I1315M | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV99242958; called by muse, mutect2, varscan2
- NKG7 | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52467423, COSV99389994; called by muse, mutect2
- NLGN2 | c.2161G>A p.G721S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100081315; called by muse, mutect2, varscan2
- NOSTRIN | c.859G>A p.E287K (on ENST00000317647 / NM_001039724.4; = p.E209K on NM_052946.3) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100474158; called by muse, mutect2, varscan2
- NPSR1 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100707272; called by muse, mutect2, varscan2
- NR2C1 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 38/124 reads (31%) | catalogued as COSV100280700; called by muse, mutect2, varscan2
- NRXN2 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs1246836172, COSV55450790, COSV55461280; called by muse, mutect2, varscan2
- NSD3 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs775871355, COSV100388977; called by muse, mutect2, varscan2
- NSUN7 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100349822, COSV57275621; called by muse, mutect2, varscan2
- NUDCD3 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs747911756, COSV100819441; called by muse, mutect2, varscan2
- NUDT13 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100624873; called by muse, mutect2, varscan2
- NUP155 | c.1933C>G p.Q645E (on ENST00000231498 / NM_153485.3; = p.Q586E on NM_004298.4) | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99195395; called by muse, mutect2, varscan2
- NXNL1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV100112044, COSV100112072; called by muse, mutect2, varscan2
- NXPE4 | c.1375C>T p.Q459* (on ENST00000375478 / NM_001077639.2; = p.Q175* on NM_017678.3) | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV100970576; called by muse, mutect2, varscan2
- OBI1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762999219, COSV56145133; called by muse, mutect2, varscan2
- OPA1 | c.655G>A p.E219K (on ENST00000361510 / NM_130837.3; = p.E201K on NM_015560.3) | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.118); catalogued as COSV62482335; called by muse, mutect2, varscan2
- OR10A3 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100660342; called by muse, mutect2, varscan2
- OR10G4 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57977317; called by muse, mutect2
- OR12D2 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV101011495; called by muse, mutect2, varscan2
- OR2M7 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100522724, COSV58740073; called by muse, mutect2, varscan2
- OR2T12 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100528038; called by muse, mutect2, varscan2
- OR3A2 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs999777842, COSV101375089; called by muse, mutect2, varscan2
- OR4D10 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV101597035; called by muse, mutect2, varscan2
- OR51V1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754234762, COSV100343538; called by muse, mutect2, varscan2
- OR56B4 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100337702, COSV57204737; called by muse, mutect2, varscan2
- OR5D14 | c.187T>A p.F63I | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV100162653; called by muse, mutect2, varscan2
- OSBP | c.209C>G p.P70R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV55662337; called by muse, mutect2
- OSBPL1A | c.2101G>T p.E701* (on ENST00000319481 / NM_080597.4; = p.E188* on NM_018030.4) | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100112920; called by muse, mutect2, varscan2
- OTX2 | c.506C>T p.S169F (on ENST00000408990 / NM_172337.3; = p.S177F on NM_021728.4) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59766304; called by muse, mutect2
- PALB2 | c.2891G>A p.G964E | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55167930, COSV99849071; called by muse, mutect2, varscan2
- PARP2 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99163079; called by muse, mutect2, varscan2
- PARP2 | c.258G>C p.L86F | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as COSV99163080; called by muse, mutect2, varscan2
- PCDH15 | c.5341C>T p.P1781S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs938596168, COSV57357456; called by muse, mutect2
- PCDHA2 | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as COSV100974174; called by muse, mutect2, varscan2
- PCGF2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs746734324; called by muse, mutect2, varscan2
- PCNX1 | c.4248C>G p.I1416M | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as COSV53089240, COSV99457501; called by muse, mutect2, varscan2
- PCTP | c.375G>C p.M125I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99273907; called by muse, mutect2, varscan2
- PDCD6IP | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1446289137, COSV56244248, COSV56246361; called by muse, mutect2, varscan2
- PDPN | c.332-1G>C p.X111_splice (on ENST00000621990; = p.X187_splice on NM_006474.4) | Splice Site (SNP) | VAF 28/119 reads (24%) | catalogued as COSV99611932; called by muse, mutect2, varscan2
- PDSS1 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100873633; called by muse, mutect2
- PELI2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.146); catalogued as rs557894615, COSV50710236; called by muse, mutect2, varscan2
- PFAS | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119194; called by muse, mutect2, varscan2
- PFKFB3 | c.321G>C p.L107F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | PolyPhen probably damaging (0.991); catalogued as COSV57987249, COSV57991530; called by muse, mutect2, varscan2
- PGD | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99581787; called by muse, mutect2, varscan2
- PGR | c.1817G>C p.R606T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54799356, COSV99679235; called by muse, mutect2, varscan2
- PHF1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV100992697; called by muse, mutect2, varscan2
- PHF11 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV100710662; called by muse, mutect2, varscan2
- PHF19 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV65877917; called by muse, mutect2, varscan2
- PIBF1 | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.398); catalogued as COSV100412025; called by muse, mutect2, varscan2
- PIK3C2G | c.3443G>T p.R1148I (on ENST00000676171; = p.R1107I on NM_004570.5) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99854288; called by muse, mutect2, varscan2
- PKDREJ | c.4772C>T p.S1591F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99479619; called by muse, mutect2, varscan2
- PKMYT1 | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99234314; called by muse, mutect2, varscan2
- PKP1 | c.1899G>A p.G633= | Splice Region (SNP) | VAF 25/89 reads (28%) | catalogued as rs767088710, COSV99825785; called by muse, mutect2, varscan2
- PLEKHA5 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100164828; called by muse, mutect2
- PML | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99167992; called by muse, mutect2, varscan2
- POLB | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV99612474, COSV99612959; called by muse, mutect2, varscan2
- POLR1A | c.2528G>C p.R843P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV55689100, COSV99808547; called by muse, mutect2, varscan2
- POU3F4 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100937346, COSV64541926; called by muse, mutect2, varscan2
- PPEF1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV100584080, COSV62995370; called by muse, mutect2, varscan2
- PPIG | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53644600; called by muse, mutect2, varscan2
- PPME1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60295890; called by muse, mutect2
- PPRC1 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.368); catalogued as COSV99532199; called by muse, mutect2, varscan2
- PRDM10 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100457074; called by muse, mutect2, varscan2
- PRDX2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100040395; called by muse, mutect2, varscan2
- PRKD2 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52186631, COSV99354692; called by muse, mutect2, varscan2
- PRKDC | c.12245G>C p.R4082P | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV100043243, COSV58070439; called by muse, mutect2, varscan2
- PRKDC | c.8911C>T p.Q2971* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as COSV100043245; called by muse, mutect2, varscan2
- PRSS54 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338364592, COSV99541262; called by muse, mutect2, varscan2
- PSD4 | c.1311G>C p.W437C | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99831516; called by muse, mutect2
- PSG9 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs767140008, COSV52483990; called by muse, mutect2, varscan2
- PSME2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.059); catalogued as COSV99395747; called by muse, mutect2, varscan2
- PTMA | c.286G>A p.E96K (on ENST00000341369 / NM_001099285.2; = p.E95K on NM_002823.5) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV100398501; called by muse, mutect2, varscan2
- PTMA | c.295G>A p.D99N (on ENST00000341369 / NM_001099285.2; = p.D98N on NM_002823.5) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs980241262, COSV100398372; called by muse, mutect2, varscan2
- RAB3B | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV63228405; called by muse, mutect2, varscan2
- RAB3IP | c.751G>C p.E251Q (on ENST00000550536 / NM_175623.4; = p.E235Q on NM_022456.5) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56083281, COSV99923722; called by muse, mutect2, varscan2
- RAB4B | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100826454; called by muse, mutect2, varscan2
- RABL6 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs1023769736, COSV100273793; called by muse, mutect2, varscan2
- RALGAPA1 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs370292880; called by muse, mutect2, varscan2
- RAPGEF4 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV99911874; called by muse, mutect2, varscan2
- RASA1 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV99171102; called by muse, mutect2
- RB1 | c.1510C>G p.Q504E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.094); catalogued as CM030506, COSV57295964, COSV99927064; called by muse, mutect2, varscan2
- RBL1 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as COSV100727326; called by muse, mutect2, varscan2
- RBM26 | c.2425C>G p.Q809E (on ENST00000438737 / NM_001366735.2; = p.Q782E on NM_022118.5) | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.93); catalogued as rs767337631, COSV99936693; called by muse, mutect2, varscan2
- RBM42 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV99387258; called by muse, mutect2, varscan2
- RBMS2 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV100008723; called by muse, mutect2, varscan2
- RECQL5 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100512395, COSV58645599; called by muse, mutect2, varscan2
- REG3G | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99709752; called by muse, mutect2, varscan2
- RGS2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52459278, COSV99343488; called by muse, mutect2, varscan2
- RGS21 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101314099; called by muse, mutect2, varscan2
- RHBDF2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100489724; called by muse, mutect2, varscan2
- RIMS2 | c.2104C>T p.Q702* (on ENST00000666250 / NM_001348490.2; = p.Q510* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 53/219 reads (24%) | catalogued as rs1327853867, COSV99202307; called by muse, mutect2, varscan2
- RIOK2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99300269; called by muse, mutect2, varscan2
- RIPOR3 | c.2316G>C p.Q772H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1237446177, COSV99247290; called by muse, mutect2, varscan2
- RNF19A | c.1881C>G p.F627L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100348179; called by muse, mutect2, varscan2
- RNF20 | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101206588; called by muse, mutect2, varscan2
- RNF44 | c.842G>C p.R281T | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV99222023; called by muse, mutect2, varscan2
- RPL9 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV99787560; called by muse, mutect2, varscan2
- RPLP0 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99935513; called by muse, mutect2, varscan2
- RPS6 | c.9G>A p.L3= | Splice Region (SNP) | VAF 29/107 reads (27%) | catalogued as COSV100194652; called by muse, mutect2, varscan2
- RPS6KA1 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100838010; called by muse, mutect2, varscan2
- RPTN | c.706C>A p.Q236K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV100285856, COSV60169216; called by muse, mutect2, varscan2
- RRAGC | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV100883867; called by muse, mutect2, varscan2
- RRP7A | c.461-1G>A p.X154_splice | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100543964; called by muse, mutect2, varscan2
- RSPH3 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.048); catalogued as COSV51923833, COSV99396618; called by muse, mutect2, varscan2
- RSPO3 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.689); catalogued as COSV63150557, COSV63150987; called by muse, mutect2, varscan2
- RTL4 | c.759G>C p.K253N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100466175; called by muse, mutect2, varscan2
- RTL6 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100373892; called by muse, mutect2, varscan2
- RTL9 | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as rs761725936, COSV101511814; called by muse, mutect2, varscan2
- RUFY3 | c.1158G>C p.E386D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV99888114; called by muse, mutect2, varscan2
- RYR1 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617167, COSV62093753; called by muse, mutect2, varscan2
- RYR1 | c.8393C>T p.S2798L | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100617168; called by muse, mutect2, varscan2
- S100PBP | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs1304431320, COSV100758403; called by muse, mutect2, varscan2
- SALL1 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as CM075000, COSV99192191; called by muse, mutect2
- SAMD4A | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as COSV99200857; called by muse, mutect2, varscan2
- SAR1B | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101284209; called by muse, mutect2, varscan2
- SCAF1 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV100862321; called by muse, mutect2, varscan2
- SCAF1 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV100862322; called by muse, mutect2, varscan2
- SDAD1 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV62403228; called by muse, mutect2, varscan2
- SEMA5A | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101228749; called by muse, mutect2, varscan2
- SENP3 | c.1678C>A p.R560S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99548635, COSV99549285; called by muse, mutect2, varscan2
- SEPTIN2 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1164220458, COSV100764997; called by muse, mutect2, varscan2
- SETD2 | c.7582G>C p.E2528Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100340162; called by muse, mutect2, varscan2
- SGO2 | c.3240G>C p.K1080N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV100764814; called by muse, mutect2, varscan2
- SHMT2 | c.1121C>G p.S374* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100197449; called by muse, mutect2
- SHOC1 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV100598079; called by muse, mutect2, varscan2
- SIN3A | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100845252; called by muse, mutect2, varscan2
- SLAMF1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99349300; called by muse, mutect2, varscan2
- SLC12A4 | c.2817G>C p.M939I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV99863349; called by muse, mutect2, varscan2
- SLC22A14 | c.1091C>G p.T364S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV99828386; called by muse, mutect2, varscan2
- SLC22A7 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV101000878; called by muse, mutect2, varscan2
- SLC26A5 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59700371; called by muse, mutect2, varscan2
- SLC38A10 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs373504148; called by muse, mutect2, varscan2
- SLC39A1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV100135721; called by muse, mutect2, varscan2
- SLC3A1 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as rs1270931874, COSV99577727; called by muse, mutect2, varscan2
- SLC40A1 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99656570; called by muse, mutect2, varscan2
- SLC44A4 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs11551744; called by muse, mutect2, varscan2
- SLC8A1 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as COSV100247572, COSV60485241; called by muse, mutect2, varscan2
- SLC8A2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1006556240, COSV99370358; called by muse, mutect2, varscan2
- SLC8A2 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV52641148, COSV99370360; called by muse, mutect2
- SLC9A7 | c.1472C>A p.A491E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100092850; called by muse, mutect2
- SMC1A | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.376); catalogued as COSV100447708; called by muse, mutect2, varscan2
- SMC4 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100644144, COSV61004964; called by muse, mutect2, varscan2
- SMPDL3B | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV65870142; called by muse, mutect2, varscan2
- SMYD5 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV99243058; called by muse, mutect2, varscan2
- SMYD5 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs777868848, COSV99240378; called by muse, mutect2, varscan2
- SNTA1 | c.1201C>G p.H401D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54128307, COSV99458990; called by muse, mutect2, varscan2
- SNX6 | c.1180G>C p.E394Q (on ENST00000652385; = p.E266Q on NM_021249.5) | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100751592; called by muse, mutect2, varscan2
- SOX1 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100447157, COSV58378261; called by muse, mutect2, varscan2
- SOX9 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55428815, COSV99818797; called by muse, mutect2, varscan2
- SP100 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414520; called by muse, mutect2, varscan2
- SPAG8 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.511); catalogued as rs769354128, COSV99428201; called by muse, mutect2, varscan2
- SPART | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62083656; called by muse, mutect2, varscan2
- SPEF2 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as rs1390290068, COSV100609060; called by muse, mutect2, varscan2
- SPESP1 | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV52986997; called by muse, mutect2, varscan2
- SPIN4 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100633422; called by muse, mutect2, varscan2
- SPPL2C | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100234185; called by muse, mutect2
- SPTAN1 | c.7090G>T p.E2364* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100824085; called by muse, varscan2
- SPTBN5 | c.6823G>A p.E2275K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100312305, COSV99077566; called by muse, mutect2, varscan2
- SRPK2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1197015608, COSV100624402; called by muse, mutect2, varscan2
- SSPOP | n.10091G>C | Splice Region (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100948152; called by muse, mutect2, varscan2
- ST7L | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99861948; called by muse, mutect2, varscan2
- STAB1 | c.4239G>A p.Q1413= | Splice Region (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100402358; called by muse, mutect2, varscan2
- STK31 | c.2873G>C p.R958T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV63457305; called by muse, mutect2, varscan2
- STRN3 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100671106; called by muse, mutect2, varscan2
- STX8 | c.155A>T p.K52M | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1289168806, COSV100111513; called by muse, mutect2
- SUGP2 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100432404; called by muse, mutect2, varscan2
- SUGT1 | c.463C>G p.Q155E (on ENST00000343788 / NM_001130912.3; = p.Q123E on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100139722; called by muse, mutect2, varscan2
- SULT1C4 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1451490598, COSV99731885; called by muse, mutect2, varscan2
- SUMF1 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99795199; called by muse, mutect2, varscan2
- SUPT6H | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100112834; called by muse, mutect2, varscan2
- SUPT6H | c.1074G>C p.K358N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100112836; called by muse, mutect2, varscan2
- SYNE1 | c.24261G>C p.Q8087H (on ENST00000367255 / NM_182961.4; = p.Q8016H on NM_033071.3) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs755660836, COSV99581669; called by muse, mutect2, varscan2
- TAF11 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV100781095; called by muse, mutect2, varscan2
- TAOK2 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs776843842, COSV99665619; called by muse, mutect2, varscan2
- TARS1 | c.2161G>C p.E721Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV99466540; called by muse, mutect2, varscan2
- TAS2R20 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as COSV101115752; called by muse, mutect2, varscan2
- TBC1D12 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99831865; called by muse, mutect2
- TBC1D2 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV100580248; called by muse, mutect2, varscan2
- TBL1XR1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553808356, COSV70500775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBPL1 | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99393995; called by muse, mutect2, varscan2
- TBR1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV101271556; called by muse, mutect2, varscan2
- TCHH | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 27/152 reads (18%) | PolyPhen benign (0.003); catalogued as rs745690939, COSV100915483; called by muse, mutect2, varscan2
- TECPR1 | c.2956G>A p.D986N | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs769357623, COSV101130797; called by muse, mutect2, varscan2
- TEK | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as rs910332944, COSV101193618; called by muse, mutect2, varscan2
- TET1 | c.6292G>A p.V2098I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101019006; called by muse, mutect2, varscan2
- TEX10 | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as COSV100887985; called by muse, mutect2
- TFCP2 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99227881; called by muse, mutect2, varscan2
- TFCP2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV56934394, COSV99227882; called by muse, mutect2, varscan2
- THADA | c.5161C>G p.L1721V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV100369592; called by muse, mutect2, varscan2
- THOC2 | c.4778G>C p.R1593T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99834327; called by muse, mutect2, varscan2
- TICRR | c.4961C>G p.S1654C | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV99180445; called by muse, mutect2, varscan2
- TICRR | c.5093C>T p.S1698F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as rs373178516, COSV99180456; called by muse, mutect2, varscan2
- TIMELESS | c.3626G>T p.*1209Lext*48 | Nonstop Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99974392; called by muse, varscan2
- TINAGL1 | c.1202C>A p.S401* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99593122; called by muse, mutect2, varscan2
- TKTL2 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99761803; called by muse, mutect2, varscan2
- TMEM132A | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV50000008; called by muse, mutect2, varscan2
- TMEM132E | c.930C>G p.F310L (on ENST00000321639; = p.F400L on NM_001304438.2) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.391); catalogued as COSV100396850; called by mutect2, varscan2
- TMF1 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV101275474; called by muse, mutect2, varscan2
- TMIGD3 | c.680C>G p.S227C (on ENST00000369717 / NM_001081976.2; = p.S308C on NM_020683.7) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.372); catalogued as COSV100778435; called by muse, mutect2, varscan2
- TNFAIP8 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.041); catalogued as COSV99174317; called by muse, mutect2, varscan2
- TNS4 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV99564195; called by muse, mutect2, varscan2
- TOM1 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs371791801; called by muse, mutect2, varscan2
- TOMM34 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100861939; called by muse, mutect2, varscan2
- TOMM70 | c.352A>T p.K118* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99424638; called by muse, mutect2, varscan2
- TRAK2 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs760612528, COSV100217197; called by muse, mutect2, varscan2
- TRAPPC10 | c.2569C>G p.Q857E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV99379256; called by muse, mutect2, varscan2
- TRMT2B | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100105721; called by muse, mutect2, varscan2
- TRPM1 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376701394, COSV56632422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPM7 | c.2259G>A p.M753I | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV100540400; called by muse, mutect2, varscan2
- TTC30B | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV68809266, COSV68809725; called by muse, mutect2, varscan2
- TTN | c.73510G>A p.E24504K (on ENST00000591111; = p.E17080K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen possibly damaging (0.54); catalogued as rs1405668603, COSV100633067; called by muse, mutect2, varscan2
- UACA | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100537826; called by muse, mutect2, varscan2
- UBA1 | c.658A>T p.M220L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100256160; called by muse, mutect2, varscan2
- UBL5 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100694872; called by muse, mutect2, varscan2
- UBR4 | c.4124C>G p.S1375C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV100922031; called by muse, mutect2, varscan2
- UHRF1 | c.1794C>G p.I598M (on ENST00000612630 / NM_001290050.1; = p.I611M on NM_013282.4) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs773988215, COSV99503759; called by muse, mutect2, varscan2
- USH2A | c.9224G>C p.R3075T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.115); catalogued as rs770809696, COSV56432970; called by muse, mutect2, varscan2
- USH2A | c.8165C>T p.S2722L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs1558146166, COSV100243392; called by mutect2, varscan2
- USP22 | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99820532; called by muse, mutect2, varscan2
- USP26 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs1158099850, COSV63708927; called by muse, mutect2, varscan2
- USP29 | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54145082, COSV99518779; called by muse, mutect2, varscan2
- USP9X | c.6508G>A p.E2170K | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100200198, COSV61065665; called by muse, mutect2, varscan2
- UTP11 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); catalogued as COSV100885003; called by muse, mutect2, varscan2
- UTP23 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV99412369; called by muse, mutect2
- VGLL2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746120919, COSV58310016; called by muse, mutect2, varscan2
- VILL | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV99379327; called by muse, mutect2, varscan2
- VIPAS39 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100493293; called by muse, mutect2, varscan2
- VPS13C | c.5354G>A p.R1785K (on ENST00000644861 / NM_020821.3; = p.R1742K on NM_017684.5) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99830488; called by muse, mutect2, varscan2
- WASF2 | c.267G>A p.V89= | Splice Region (SNP) | VAF 31/107 reads (29%) | catalogued as COSV101420828; called by muse, mutect2, varscan2
- WDR33 | c.3044G>A p.R1015K | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.191); catalogued as COSV100460761; called by muse, varscan2
- WDR33 | c.2983G>T p.D995Y | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV100460762; called by muse, varscan2
- WDR88 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV100866649; called by muse, mutect2, varscan2
- WNK3 | c.2455C>T p.H819Y | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV63614185; called by muse, mutect2, varscan2
- WRAP73 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.424); catalogued as COSV54563841; called by muse, mutect2, varscan2
- WWC3 | c.2116C>G p.Q706E | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101081903; called by muse, mutect2, varscan2
- XDH | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as COSV101052496; called by muse, mutect2, varscan2
- XYLT2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV99191251; called by muse, mutect2, varscan2
- YTHDF2 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100863863; called by muse, mutect2, varscan2
- ZBTB3 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV101189011; called by muse, mutect2, varscan2
- ZBTB34 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100044025; called by muse, mutect2, varscan2
- ZBTB7B | c.130G>A p.E44K (on ENST00000292176; = p.E78K on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV52692164; called by muse, mutect2, varscan2
- ZC2HC1C | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as COSV99472992; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1967C>A p.S656* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV99649147; called by muse, mutect2, varscan2
- ZFP91 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100284776, COSV60159271; called by muse, mutect2, varscan2
- ZNF154 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101377554; called by muse, mutect2, varscan2
- ZNF160 | c.2153C>G p.S718* | Nonsense Mutation (SNP) | VAF 17/211 reads (8%) | catalogued as COSV100762303, COSV100762500; called by muse, mutect2
- ZNF226 | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100335282; called by muse, varscan2
- ZNF226 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV56197672; called by muse, mutect2, varscan2
- ZNF229 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV99351030; called by muse, mutect2, varscan2
- ZNF25 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV100224807, COSV56922084; called by muse, mutect2, varscan2
- ZNF283 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV100191122; called by muse, mutect2, varscan2
- ZNF324B | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100351829; called by muse, mutect2, varscan2
- ZNF33A | c.985G>A p.E329K (on ENST00000458705 / NM_006974.3; = p.E330K on NM_006954.2) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV100276280; called by muse, mutect2, varscan2
- ZNF354B | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as COSV100483147; called by muse, mutect2
- ZNF385D | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99876627; called by muse, mutect2
- ZNF462 | c.7021G>A p.E2341K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV99473526; called by muse, mutect2, varscan2
- ZNF479 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV100483128; called by muse, mutect2
- ZNF518B | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58722312, COSV58722747; called by muse, mutect2, varscan2
- ZNF548 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1270350323, COSV100278314; called by muse, mutect2, varscan2
- ZNF586 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.099); catalogued as COSV101197715, COSV66972692; called by muse, mutect2, varscan2
- ZNF678 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV100652996; called by muse, mutect2, varscan2
- ZNF835 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV101606412; called by muse, mutect2, varscan2
- ZP1 | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV53924949, COSV99612170; called by muse, mutect2, varscan2
- ZYX | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs758266725, COSV100503859; called by muse, mutect2, varscan2
- ACACA | c.5837C>G p.S1946* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- ANAPC1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.173); called by mutect2, varscan2
- BMP2 | c.113C>G p.S38W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- CCL14 | c.9C>G p.I3M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCL23 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ESR1 | c.229_236del p.G77Lfs*6 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- MRPL45 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- MUC2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR3A3 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB10 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- TMIE | c.232_241del p.F78Vfs*61 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel
- TPTE | c.379C>G p.R127G (on ENST00000618007 / NM_199261.4; = p.R109G on NM_199259.4) | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, varscan2
- ZNF658 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- ABCA4 | c.6630C>G p.V2210= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100933306; called by muse, mutect2, varscan2
- ABCC1 | c.2328G>C p.V776= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100580453; called by muse, mutect2, varscan2
- ABCD1 | c.1905G>A p.V635= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs1458996259, COSV99497952; called by muse, mutect2, varscan2
- ADAMTS17 | c.2142C>G p.L714= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99171814; called by muse, mutect2, varscan2
- ADAMTSL4 | c.54C>T p.L18= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV99648120; called by muse, mutect2, varscan2
- ADCY2 | c.2514C>T p.F838= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100604377; called by muse, mutect2, varscan2
- ADCY5 | c.1482C>G p.L494= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100568328; called by muse, mutect2, varscan2
- ADGRA2 | c.1575C>T p.A525= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs759216475, COSV100178482; called by muse, mutect2, varscan2
- ADGRA2 | c.2520C>T p.I840= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99605165; called by muse, mutect2
- ADGRG2 | c.1593G>A p.L531= (on ENST00000379869 / NM_001079858.3; = p.L528= on NM_005756.4) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100492497, COSV100492779; called by muse, mutect2, varscan2
- AKAP8 | c.798C>G p.G266= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99512216; called by muse, mutect2, varscan2
- AKR1C1 | c.339C>G p.L113= | Silent (SNP) | VAF 45/193 reads (23%) | catalogued as COSV101080559, COSV101080586; called by muse, mutect2, varscan2
- AMPH | c.1764G>A p.Q588= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs71548609, COSV100342055, COSV100343880; called by muse, mutect2, varscan2
- AOPEP | c.2046G>C p.T682= (on ENST00000375315 / NM_001193329.1; = p.T583= on NM_032823.5) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99951027; called by muse, varscan2
- APBA2 | c.54G>A p.V18= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1444060314, COSV101382574; called by muse, mutect2, varscan2
- APOBR | c.1671G>A p.L557= (on ENST00000431282; = p.L566= on NM_018690.4) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100112980, COSV60492998; called by muse, mutect2, varscan2
- ARHGEF6 | c.300G>A p.L100= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV99166775; called by muse, mutect2, varscan2
- ARL13A | c.90C>T p.N30= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV101502343; called by muse, mutect2, varscan2
- BDKRB2 | c.336C>T p.F112= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100021536; called by muse, mutect2, varscan2
- BOC | c.159G>C p.V53= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99849485; called by muse, mutect2, varscan2
- BPI | c.333C>T p.I111= (on ENST00000262865; = p.I107= on NM_001725.3) | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99481005; called by muse, mutect2, varscan2
- BRCA1 | c.2802G>A p.Q934= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100525212; called by muse, mutect2, varscan2
- CA11 | c.447C>T p.I149= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99320889; called by muse, mutect2, varscan2
- CACNB2 | c.1369C>T p.L457= (on ENST00000324631 / NM_201596.3; = p.L402= on NM_000724.4) | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV56653852, COSV99030389; called by muse, mutect2, varscan2
- CALCOCO2 | c.840G>A p.K280= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99363679, COSV99363983; called by muse, mutect2, varscan2
- CAPN11 | c.1131C>T p.L377= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV101291967; called by muse, mutect2, varscan2
- CCDC33 | c.1173G>A p.L391= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1192693688, COSV100351917; called by muse, mutect2, varscan2
- CCND2 | c.312C>G p.V104= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99714505; called by muse, mutect2, varscan2
- CD177 | c.750C>G p.L250= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as COSV100946099, COSV65121723; called by muse, mutect2, varscan2
- CDH2 | c.138G>A p.S46= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs757068729, COSV52270140, COSV52276008; called by muse, mutect2, varscan2
- CDKL1 | c.708C>T p.F236= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV53581025, COSV99367968; called by muse, mutect2, varscan2
- CENPF | c.1527C>G p.L509= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV100871446; called by muse, mutect2, varscan2
- CEP85L | c.1836C>G p.L612= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV100874399; called by muse, mutect2, varscan2
- CHD5 | c.3393C>T p.F1131= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV52417678; called by muse, mutect2
- CHRNA7 | c.1146G>A p.G382= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as COSV60968797; called by muse, mutect2, varscan2
- CLIC5 | c.1232G>A p.*411= (on ENST00000185206 / NM_001370649.1; = p.*252= on NM_016929.5) | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV99485487; called by muse, mutect2, varscan2
- CLIC5 | c.681C>T p.P227= (on ENST00000185206 / NM_001370649.1; = p.P68= on NM_016929.5) | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs151203192; called by muse, mutect2, varscan2
- CLPTM1L | c.675G>C p.L225= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100307389, COSV57993456; called by muse, mutect2, varscan2
- CNTN5 | c.1926G>A p.L642= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV54288538; called by muse, mutect2, varscan2
- COA7 | c.453C>T p.F151= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101034482; called by muse, mutect2, varscan2
- COL1A2 | c.3924C>T p.F1308= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99801307; called by muse, mutect2, varscan2
- COL7A1 | c.3480G>A p.V1160= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1198960247, COSV100097863; called by muse, mutect2, varscan2
- CSPG4 | c.5301C>G p.L1767= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV100414234; called by muse, mutect2
- CXCR2 | c.759C>T p.I253= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100579191; called by muse, mutect2, varscan2
- DDHD1 | c.1461C>T p.I487= (on ENST00000323669; = p.I684= on NM_030637.3) | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as COSV100080176; called by muse, mutect2, varscan2
- DDIAS | c.2496G>A p.Q832= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100231485; called by muse, mutect2, varscan2
- DIS3L2 | c.1458C>T p.I486= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99806136, COSV99807418; called by muse, mutect2, varscan2
- DMAC2 | c.165G>C p.L55= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV55727763, COSV99700749; called by muse, mutect2
- DMD | c.8619G>A p.L2873= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as COSV100629655, COSV58933115; called by muse, mutect2, varscan2
- DNALI1 | c.780C>T p.F260= (on ENST00000296218; = p.F238= on NM_003462.5) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99953773; called by muse, mutect2, varscan2
- DOCK6 | c.1491G>A p.K497= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV99371126; called by muse, mutect2, varscan2
- DPP10 | c.963C>T p.I321= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs1223303709, COSV100072506; called by muse, mutect2
- DYNC2H1 | c.8214C>G p.L2738= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV100519924; called by muse, mutect2, varscan2
- ECM2 | c.771G>A p.E257= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100755984; called by muse, mutect2, varscan2
- EDDM3B | c.435C>T p.I145= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs755986649, COSV58746945; called by muse, varscan2
- ELMO1 | c.1141C>T p.L381= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100166348, COSV60311202; called by muse, mutect2, varscan2
- ELP1 | c.3666G>A p.L1222= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV101010525; called by muse, mutect2, varscan2
- EPHA5 | c.930C>T p.F310= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99901668; called by muse, mutect2, varscan2
- EPS15L1 | c.624C>T p.L208= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs775172507, COSV99933811; called by muse, mutect2, varscan2
- ERRFI1 | c.1138C>T p.L380= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV101088330; called by muse, mutect2, varscan2
- ETNK1 | c.474C>T p.I158= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV99861054; called by muse, mutect2, varscan2
- FAM114A1 | c.744C>A p.G248= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100729510; called by muse, mutect2, varscan2
- FAM71E1 | c.534C>G p.L178= (on ENST00000600100 / NM_001308429.2; = p.L162= on NM_138411.3) | Silent (SNP) | VAF 71/193 reads (37%) | catalogued as COSV100618561; called by muse, mutect2, varscan2
- FANCD2 | c.3150G>A p.V1050= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99812716; called by muse, mutect2, varscan2
- FBXW4 | c.582C>T p.I194= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- FDX2 | c.39G>C p.V13= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99533191; called by muse, mutect2, varscan2
- FLOT2 | c.522G>A p.V174= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV101204814; called by muse, mutect2, varscan2
- GET3 | c.546C>T p.I182= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs758825720, COSV100628298; called by muse, mutect2, varscan2
- GMCL1 | c.408C>T p.F136= | Silent (SNP) | VAF 46/175 reads (26%) | catalogued as rs779744664, COSV99247971; called by muse, mutect2, varscan2
- GNB2 | c.153C>T p.L51= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99310125; called by muse, mutect2, varscan2
- GNPTAB | c.3003C>G p.L1001= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100172471, COSV68449714; called by muse, mutect2, varscan2
- GON4L | c.3681G>T p.V1227= | Silent (SNP) | VAF 58/188 reads (31%) | catalogued as COSV99675951; called by muse, mutect2, varscan2
- GOT1L1 | c.546G>C p.V182= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100294754; called by muse, mutect2, varscan2
- GPR1 | c.252C>T p.F84= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV101329876, COSV67976535; called by muse, mutect2, varscan2
- GPX6 | c.138C>T p.L46= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100724925; called by muse, mutect2, varscan2
- GREM2 | c.147C>T p.I49= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100548049; called by muse, mutect2, varscan2
- HELLS | c.2469C>T p.F823= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99492464; called by muse, mutect2, varscan2
- HERC2 | c.9126C>G p.L3042= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV55309119; called by muse, mutect2, varscan2
- HOXC6 | c.621G>A p.S207= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV99679037, COSV99679220; called by muse, varscan2
- HPX | c.958C>T p.L320= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99793582; called by muse, mutect2, varscan2
- HS3ST4 | c.969G>A p.L323= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100503257; called by muse, mutect2, varscan2
- HUWE1 | c.8544C>A p.V2848= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99474560; called by muse, mutect2, varscan2
- IMMT | c.1119G>A p.L373= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV99607684; called by muse, mutect2, varscan2
- INTS2 | c.486C>T p.F162= | Silent (SNP) | VAF 46/196 reads (23%) | catalogued as COSV52152764; called by muse, varscan2
- IRAK1 | c.648C>G p.L216= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100318552, COSV57656325; called by muse, mutect2, varscan2
- JADE3 | c.1308G>A p.L436= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99510398; called by muse, mutect2, varscan2
- KCNK7 | c.129C>G p.L43= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100442389; called by muse, mutect2, varscan2
- KIF14 | c.90C>A p.L30= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100951104; called by muse, mutect2, varscan2
- KLHL12 | c.1398A>T p.A466= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV66127529; called by muse, mutect2, varscan2
- KLRC4 | c.306G>A p.Q102= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV58672537; called by muse, mutect2
- KRT15 | c.330G>A p.Q110= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as rs1328402672, COSV99563328; called by muse, mutect2, varscan2
- LCAT | c.1125C>G p.R375= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99863346; called by muse, mutect2, varscan2
- LHX2 | c.234C>G p.L78= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs1310949952, COSV101010098; called by muse, mutect2, varscan2
- LIMK2 | c.837G>A p.L279= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100059124; called by muse, mutect2, varscan2
- LYST | c.11085C>T p.L3695= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs767062870, COSV101090410; called by muse, mutect2, varscan2
- MAP3K9 | c.858C>T p.S286= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs780232704, COSV101173410, COSV101173789; called by muse, mutect2, varscan2
- MAT1A | c.138C>T p.L46= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100944499; called by muse, mutect2, varscan2
- MEIS3 | c.435G>A p.L145= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1316427636, COSV100520588; called by muse, mutect2, varscan2
138 further variants in this file (0 protein-altering or splice-affecting, 117 silent, 21 other) are not listed here.
